Somatic mutation profile of tumor specimen TARGET-40-PAMYYJ-01A (aliquot TARGET-40-PAMYYJ-01A-01D) from TARGET case TARGET-40-PAMYYJ, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.7 years (6,477 days).
Specimen TARGET-40-PAMYYJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7af9f1cb-8b59-4a49-be68-c375ccd45fa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAMYYJ-10A (Blood Derived Normal), aliquot TARGET-40-PAMYYJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/596776c7-446a-4d5c-84fb-e9df31d609de

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Frame Shift Del 3, Intron 3, Silent 3, RNA 2, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.3969C>G p.S1323R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100711107; called by muse, mutect2, varscan2
- ATRX | c.3365del p.C1122Lfs*8 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as COSV64871832; called by mutect2, pindel, varscan2
- HCN1 | c.2309G>A p.S770N | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as rs369380065; called by muse, mutect2, varscan2
- SLC45A2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs374649089, COSV56874513; called by muse, mutect2, varscan2
- SNX20 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV56057536; called by muse, mutect2
- ANKRD36C | c.2478G>T p.K826N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- CCDC151 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 73/130 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CD5 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEACAM1 | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); called by muse, mutect2
- FANCE | c.974A>C p.D325A | Missense Mutation (SNP) | VAF 66/469 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- FLG2 | c.1027T>C p.S343P | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCY1A1 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HELZ2 | c.1690A>T p.R564W | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- KIAA0319L | c.805del p.S269Vfs*38 | Frame Shift Del (DEL) | VAF 26/55 reads (47%) | called by mutect2, pindel, varscan2
- LRRN2 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 119/180 reads (66%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- MALSU1 | c.406del p.H136Mfs*8 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | called by mutect2, pindel, varscan2
- NOX4 | c.1249T>A p.F417I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- PCDH15 | c.3717+2T>G p.X1239_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- RB1 | c.1720_1721insT p.K574Ifs*11 | Frame Shift Ins (INS) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- RNF31 | c.526C>G p.Q176E | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.99); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SPP1 | c.346_348del p.D116del (on ENST00000395080 / NM_001040058.2; = p.D102del on NM_000582.2) | In Frame Del (DEL) | VAF 140/236 reads (59%) | called by pindel, varscan2
- DMXL1 | c.7707C>T p.R2569= | Silent (SNP) | VAF 28/95 reads (29%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3855C>T p.D1285= | Silent (SNP) | VAF 55/136 reads (40%) | catalogued as rs876657496, COSV56068422; ClinVar: likely benign; called by muse, mutect2, varscan2
- VAV1 | c.1296C>G p.L432= | Silent (SNP) | VAF 80/178 reads (45%) | called by muse, mutect2, varscan2
- CELSR2 | c.8745-68A>G | Intron (SNP) | VAF 54/107 reads (50%) | called by muse, mutect2, varscan2
- OR7E99P | n.28G>T | RNA (SNP) | VAF 22/46 reads (48%) | catalogued as rs1440218422; called by muse, mutect2, varscan2
- PLCB2 | c.3113+12T>C | Intron (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-6506C>T | Intron (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- WHAMMP2 | n.268T>G | RNA (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
